Somatic mutation profile of tumor specimen 0DHQEL from CCDI case PBBUMG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Mucoepidermoid carcinoma; Tissue or organ of origin: Submandibular gland; Age at diagnosis: 15.6 years (5,694 days).
Specimen 0DHQEL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90ceee05-7a57-4e05-936a-f99398e0f257.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHQDF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cb50ab9-a5ff-4168-ab09-012ca3629202

The open-access MAF lists 13 somatic variants for this specimen: 5 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 5, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTSB | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 52/1002 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as rs542527240; called by muse, mutect2
- PHF24 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 129/769 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1310156704, COSV54274514; called by muse, mutect2, varscan2
- ANKFN1 | c.1087C>A p.P363T | Missense Mutation (SNP) | VAF 152/879 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 52/1386 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 54/2054 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- AP5M1 | c.840G>C p.L280= | Silent (SNP) | VAF 44/1004 reads (4%) | called by muse, mutect2
- DOCK8 | c.5172C>T p.T1724= | Silent (SNP) | VAF 139/1224 reads (11%) | catalogued as rs773729026, COSV101210012; called by muse, mutect2, varscan2
- FBXL22 | c.36C>T p.L12= | Silent (SNP) | VAF 50/654 reads (8%) | called by muse, mutect2
- METRNL | c.483C>T p.I161= | Silent (SNP) | VAF 86/527 reads (16%) | catalogued as rs895152360; called by muse, mutect2, varscan2
- SLC15A4 | c.1345C>T p.L449= | Silent (SNP) | VAF 106/1592 reads (7%) | called by muse, mutect2
- CFAP65 | c.-2-93C>G | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- ITPR1 | c.6907+1014G>A | Intron (SNP) | VAF 16/137 reads (12%) | catalogued as rs529453312; called by muse, mutect2, varscan2
- STK25 | c.-14G>A | 5'UTR (SNP) | VAF 54/439 reads (12%) | catalogued as rs778196771; called by muse, mutect2, varscan2
